Somatic mutation profile of tumor specimen TCGA-3G-AB0Q-01A (aliquot TCGA-3G-AB0Q-01A-11D-A423-09) from TCGA case TCGA-3G-AB0Q, project TCGA-THYM (Thymoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Thymoma, type A, malignant; Tissue or organ of origin: Thymus; Age at diagnosis: 67.0 years (24,460 days).
Specimen TCGA-3G-AB0Q-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 82e9f871-df98-4d76-a37a-64a52d795bba.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-3G-AB0Q-11A (Solid Tissue Normal), aliquot TCGA-3G-AB0Q-11A-21D-A426-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b5ae967f-91ce-4569-9a8e-75ee5cd89518

The open-access MAF lists 21 somatic variants for this specimen: 19 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 16, Silent 2, Nonsense Mutation 1, In Frame Ins 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GTF2I | c.1271T>A p.L424H (on ENST00000573035 / NM_032999.4; = p.L383H on NM_001518.5) | Missense Mutation (SNP) | VAF 144/414 reads (35%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen probably damaging (0.963); catalogued as COSV60399097; called by muse, mutect2, varscan2
- AP1M1 | c.883A>C p.I295L | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT tolerated (0.15); PolyPhen benign (0.02); catalogued as rs1196680088, COSV52225260; called by muse, mutect2
- FOXN1 | c.160G>A p.D54N | Missense Mutation (SNP) | VAF 16/32 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.255); catalogued as rs200888774; ClinVar: uncertain significance; called by muse, varscan2
- HERC2 | c.11791G>T p.E3931* | Nonsense Mutation (SNP) | VAF 4/54 reads (7%) | catalogued as COSV55319355; called by muse, mutect2
- NDN | c.155C>T p.P52L | Missense Mutation (SNP) | VAF 3/13 reads (23%) | SIFT deleterious (0.05); PolyPhen benign (0.018); catalogued as rs1490061295; called by muse, mutect2
- OR1I1 | c.459C>A p.N153K | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.765); catalogued as rs771927915; called by muse, mutect2, varscan2
- RBM39 | c.1265C>A p.A422E (on ENST00000253363 / NM_001323424.2; = p.A416E on NM_004902.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 38/101 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV53615964, COSV53617768; called by muse, mutect2, varscan2
- RDH5 | c.412A>G p.M138V | Missense Mutation (SNP) | VAF 46/115 reads (40%) | SIFT tolerated (0.34); PolyPhen benign (0.021); catalogued as rs748274544, CD159656; called by muse, mutect2
- ABCC4 | c.3650A>G p.K1217R | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT tolerated (0.05); PolyPhen benign (0.342); called by muse, mutect2, varscan2
- CCDC22 | c.1657G>T p.V553F | Missense Mutation (SNP) | VAF 3/48 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2
- CLTC | c.1829G>C p.R610P | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.917); called by muse, mutect2, varscan2
- DNAJC27 | c.556T>C p.C186R | Missense Mutation (SNP) | VAF 25/115 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.321); called by muse, mutect2, varscan2
- ERC1 | c.90G>T p.L30F | Missense Mutation (SNP) | VAF 3/32 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.737); called by muse, mutect2
- FLNA | c.2319dup p.V774Sfs*48 | Frame Shift Ins (INS) | VAF 18/74 reads (24%) | called by mutect2, pindel, varscan2
- MRPS7 | c.26C>G p.A9G | Missense Mutation (SNP) | VAF 42/130 reads (32%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0); called by muse, mutect2, varscan2
- NALCN | c.2369C>T p.S790F | Missense Mutation (SNP) | VAF 6/76 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.25); called by muse, mutect2
- NHS | c.3080G>T p.G1027V | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PLXNB2 | c.2310_2312dup p.R771dup | In Frame Ins (INS) | VAF 15/57 reads (26%) | called by mutect2, pindel, varscan2
- STRIP2 | c.1214C>A p.A405E | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT tolerated (0.49); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- RPL18 | c.207G>A p.K69= | Silent (SNP) | VAF 18/49 reads (37%) | called by muse, mutect2, varscan2
- SF3B1 | c.1047C>T p.S349= | Silent (SNP) | VAF 25/60 reads (42%) | called by muse, mutect2, varscan2
